Somatic mutation profile of tumor specimen HCM-BROD-0001-C18-06A (aliquot HCM-BROD-0001-C18-06A-21D-A82H-36) from HCMI case HCM-BROD-0001-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: GX; Age at diagnosis: 47.4 years (17,316 days).
Specimen HCM-BROD-0001-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e89fdb51-f70c-436a-be07-a15b6878b12a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0001-C18-10A (Blood Derived Normal), aliquot HCM-BROD-0001-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfff964e-3e4a-4d13-a64b-475338c549f6

The open-access MAF lists 222 somatic variants for this specimen: 169 protein-altering or splice-affecting, 43 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 43, Nonsense Mutation 7, Intron 5, 5'Flank 3, Frame Shift Del 2, In Frame Ins 1, 3'Flank 1, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/132 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 171/188 reads (91%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58055203; called by muse, mutect2, varscan2
- ADGRL3 | c.1597C>T p.R533W (on ENST00000506720 / NM_001322402.2; = p.R465W on NM_015236.6) | Missense Mutation (SNP) | VAF 198/328 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs761335675; called by muse, mutect2, varscan2
- ANGPT4 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 290/579 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs746445808, COSV67921665; called by muse, mutect2, varscan2
- ATM | c.985A>G p.R329G | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53730815; called by muse, mutect2, varscan2
- BEGAIN | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 318/512 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1297371425, COSV62068140; called by muse, varscan2
- BMP10 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 72/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770302; called by muse, mutect2, varscan2
- BRD4 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 172/314 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs201971332; called by muse, mutect2, varscan2
- C1orf94 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 84/396 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV64913180; called by muse, mutect2, varscan2
- C2CD3 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 119/383 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV58102114; called by muse, mutect2, varscan2
- CACNA1C | c.4624C>T p.R1542C | Missense Mutation (SNP) | VAF 199/393 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59697521; called by muse, mutect2, varscan2
- CD1A | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 29/571 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759825385; called by muse, mutect2
- CLDN25 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746964341, COSV101493608; called by muse, mutect2
- COL18A1 | c.3973G>A p.G1325R (on ENST00000359759 / NM_130444.3; = p.G1090R on NM_030582.4) | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs767090801; called by muse, mutect2, varscan2
- CSMD1 | c.1717C>A p.Q573K (on ENST00000520002; = p.Q572K on NM_033225.6) | Missense Mutation (SNP) | VAF 167/183 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV100144606; called by muse, mutect2, varscan2
- CYP26A1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 236/608 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs200654050; called by muse, mutect2, varscan2
- DEF8 | c.1304A>G p.K435R | Missense Mutation (SNP) | VAF 91/846 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as rs1451989558; called by muse, mutect2, varscan2
- DHRS4L2 | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1266693873; called by muse, mutect2, varscan2
- DMD | c.1923A>C p.E641D | Missense Mutation (SNP) | VAF 114/860 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.132); catalogued as COSV55874842; called by muse, mutect2, varscan2
- EZHIP | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 315/931 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100539997; called by muse, mutect2, varscan2
- FAM136A | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as rs773334625; called by muse, mutect2
- FAM155B | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 149/2000 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV52935094; called by muse, mutect2
- FAM47C | c.1424G>T p.C475F | Missense Mutation (SNP) | VAF 158/976 reads (16%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.491); catalogued as COSV63723820; called by muse, mutect2, varscan2
- FAT3 | c.5335A>C p.S1779R | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53121540, COSV99971661; called by muse, mutect2, varscan2
- FIGNL2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 227/1170 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.347); catalogued as rs1408652556; called by muse, mutect2, varscan2
- GHR | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 176/264 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs949031881, COSV50119144; called by muse, mutect2, varscan2
- GXYLT2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1281977380; called by muse, mutect2, varscan2
- HEPHL1 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 160/245 reads (65%) | catalogued as rs546075822; called by muse, mutect2, varscan2
- HSD11B2 | c.943A>G p.M315V | Missense Mutation (SNP) | VAF 322/608 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs889138699; called by muse, mutect2, varscan2
- IQCF5 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 145/480 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1190575303, COSV71306819; called by muse, mutect2, varscan2
- KALRN | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 126/423 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs758760625, COSV53761733; called by muse, mutect2, varscan2
- KIAA0232 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 92/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301175; called by muse, mutect2, varscan2
- KIAA1841 | c.952C>G p.R318G | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.648); catalogued as rs199876206, COSV54374561; called by muse, mutect2, varscan2
- KRT3 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs1047519998; called by muse, mutect2, varscan2
- KTN1 | c.3947C>T p.T1316M (on ENST00000395314 / NM_001271014.2; = p.T1259M on NM_004986.4) | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs548275870; called by muse, mutect2, varscan2
- MAB21L4 | c.1154C>T p.P385L (on ENST00000388934 / NM_001085437.3; = p.P217L on NM_024861.4) | Missense Mutation (SNP) | VAF 355/743 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.47); catalogued as rs745897108, COSV56744358; called by muse, mutect2, varscan2
- MAGEB6B | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 466/619 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs749961121; called by muse, mutect2, varscan2
- MARCHF3 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 148/229 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1036345702; called by muse, mutect2, varscan2
- MUC16 | c.18386A>C p.K6129T | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.026); catalogued as rs756047781; called by muse, mutect2, varscan2
- NCKAP1L | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1165841354, COSV53207087; called by muse, mutect2, varscan2
- NETO2 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV57451169, COSV57454127; called by muse, mutect2
- NIBAN2 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 274/550 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1046063862, COSV100030967; called by muse, mutect2, varscan2
- NLRP7 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 111/581 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759837769, COSV60173232; called by muse, mutect2, varscan2
- NUMA1 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 181/550 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1314480088; called by muse, mutect2, varscan2
- OR4K5 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194359915, COSV60004330; called by muse, mutect2, varscan2
- OTOG | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs753472595; called by muse, mutect2, varscan2
- OTUD7A | c.1498G>A p.G500S (on ENST00000307050 / NM_001382637.1; = p.G493S on NM_130901.3) | Missense Mutation (SNP) | VAF 351/679 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as rs765651339, COSV61035747; called by muse, mutect2, varscan2
- PCDH11X | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 315/757 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100012288; called by muse, mutect2, varscan2
- PLXNB2 | c.594A>C p.E198D | Missense Mutation (SNP) | VAF 99/363 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.143); catalogued as COSV63780404; called by muse, mutect2, varscan2
- PRDM5 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 216/323 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs750031024, COSV53368548; called by muse, mutect2, varscan2
- PYROXD1 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs752999723; called by muse, mutect2
- RHPN1 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 305/1046 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs761122027; called by muse, mutect2, varscan2
- SAMSN1 | c.893G>T p.R298L (on ENST00000647101; = p.R70L on NM_001256370.1) | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs546183526; called by muse, mutect2
- SEMA6D | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60381371; called by muse, mutect2, varscan2
- SLCO1C1 | c.296T>G p.V99G | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56872906, COSV56873569; called by muse, mutect2, varscan2
- SLITRK2 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 281/879 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs782605442, COSV59425870; called by muse, mutect2, varscan2
- SMAD4 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 211/240 reads (88%) | catalogued as rs1568211615, CD040591, COSV61684525, COSV61684934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1B | c.2690A>C p.K897T | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.306); catalogued as COSV100663270; called by muse, mutect2, varscan2
- SNX16 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 149/295 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs368813947; called by muse, mutect2, varscan2
- TAS2R7 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 108/724 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745463796; called by muse, mutect2, varscan2
- TEX45 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 150/420 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV64463881; called by muse, mutect2, varscan2
- TMEM198 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 285/652 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1190999055; called by muse, mutect2, varscan2
- WWOX | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 140/487 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs375757102, COSV68354948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZC3H4 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 170/558 reads (30%) | catalogued as rs1160901268; called by muse, mutect2, varscan2
- ZNF480 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1326211421; called by muse, mutect2, varscan2
- ABCC6 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 39/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS12 | c.3607G>T p.D1203Y | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.2253G>C p.Q751H | Missense Mutation (SNP) | VAF 320/458 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADGRB2 | c.2546del p.P849Lfs*69 | Frame Shift Del (DEL) | VAF 152/479 reads (32%) | called by mutect2, pindel, varscan2
- ADGRL1 | c.3961G>A p.E1321K (on ENST00000340736 / NM_001008701.3; = p.E1316K on NM_014921.5) | Missense Mutation (SNP) | VAF 265/687 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ARAF | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 115/653 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARFGEF3 | c.3710T>C p.L1237P | Missense Mutation (SNP) | VAF 68/418 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 121/572 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASB4 | c.920G>A p.C307Y | Missense Mutation (SNP) | VAF 221/540 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, varscan2
- ATM | c.1970_1971del p.F657* | Frame Shift Del (DEL) | VAF 84/207 reads (41%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.766T>G p.L256V | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BIRC6 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD36 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CDC42BPB | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 293/459 reads (64%) | called by muse, mutect2, varscan2
- CELA3A | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CFAP74 | c.1764A>G p.I588M | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CHIT1 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 53/483 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CNTN4 | c.462T>G p.S154R | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CPM | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE7 | c.644A>T p.K215M | Missense Mutation (SNP) | VAF 103/459 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CPSF1 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 72/1260 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); called by muse, mutect2
- CSNKA2IP | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 87/370 reads (24%) | called by muse, mutect2, varscan2
- CST9L | c.55T>G p.L19V | Missense Mutation (SNP) | VAF 79/514 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYP11B2 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 92/1720 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- DCLK2 | c.816A>C p.E272D | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- E2F8 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 323/534 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EIF2S3 | c.1195T>G p.S399A | Missense Mutation (SNP) | VAF 91/566 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF6 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESPL1 | c.5916A>C p.E1972D | Missense Mutation (SNP) | VAF 60/362 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ESRP1 | c.1224A>C p.E408D | Missense Mutation (SNP) | VAF 40/640 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2
- FDPS | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 88/390 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FER1L6 | c.2173A>C p.S725R | Missense Mutation (SNP) | VAF 88/1512 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- FILIP1 | c.1337A>C p.K446T | Missense Mutation (SNP) | VAF 52/835 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- FOXN1 | c.1310A>T p.N437I | Missense Mutation (SNP) | VAF 100/632 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- GATA6 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 194/1583 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- GBP7 | c.969C>G p.N323K | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFRA4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 186/668 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GRAMD1C | c.406A>C p.K136Q | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB1 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- HS2ST1 | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGDCC4 | c.1610G>T p.S537I | Missense Mutation (SNP) | VAF 136/463 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IP6K2 | c.982T>G p.S328A | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ITGB7 | c.2098T>G p.F700V | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- JRKL | c.475T>G p.F159V | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KHNYN | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL22 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KLHL30 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 105/656 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- KNG1 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- KNL1 | c.6416A>C p.E2139A (on ENST00000346991 / NM_170589.5; = p.E2113A on NM_144508.5) | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARP1 | c.1616A>C p.K539T (on ENST00000518297 / NM_033551.3; = p.K462T on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); called by muse, mutect2
- LHFPL4 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 186/657 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LRRC72 | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LY75 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCOL | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPHOSPH9 | c.822T>G p.N274K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYBPHL | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 81/396 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYG1 | c.868T>G p.F290V | Missense Mutation (SNP) | VAF 73/522 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH6 | c.4178A>C p.K1393T | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO3A | c.3381A>C p.K1127N | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NDST4 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 150/216 reads (69%) | SIFT tolerated (0.31); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- NEFM | c.1689A>C p.E563D | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NF2 | c.1190T>G p.L397R | Missense Mutation (SNP) | VAF 91/381 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKX6-1 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 177/547 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NOP2 | c.1871A>C p.K624T (on ENST00000322166 / NM_001258308.2; = p.K620T on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/584 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NYNRIN | c.4691A>C p.K1564T | Missense Mutation (SNP) | VAF 83/370 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OPA1 | c.2682A>C p.Q894H (on ENST00000361510 / NM_130837.3; = p.Q839H on NM_015560.3) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, varscan2
- OR1L1 | c.827T>C p.L276P (on ENST00000373686; = p.L226P on NM_001005236.3) | Missense Mutation (SNP) | VAF 123/503 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR4F6 | c.890C>A p.A297E | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- OTOF | c.3927_3928insCAG p.K1309_K1310insQ (on ENST00000272371 / NM_194248.3; = p.K542_K543insQ on NM_004802.4) | In Frame Ins (INS) | VAF 62/403 reads (15%) | called by pindel, varscan2
- PCDHA5 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 406/622 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PIWIL2 | c.2564A>G p.K855R | Missense Mutation (SNP) | VAF 251/276 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAD21 | c.1720A>C p.T574P | Missense Mutation (SNP) | VAF 72/903 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBM11 | c.166T>A p.C56S | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- REV1 | c.2600A>C p.E867A | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ROCK1 | c.3758T>G p.F1253C | Missense Mutation (SNP) | VAF 124/237 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RUBCN | c.2071T>A p.L691M | Missense Mutation (SNP) | VAF 90/437 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SCN1A | c.1545A>C p.K515N | Missense Mutation (SNP) | VAF 17/536 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.134); called by muse, mutect2
- SCOC | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 208/580 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SELENBP1 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 50/656 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SERAC1 | c.1517A>T p.K506M | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SF3A3 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- SH2D4B | c.283A>C p.I95L | Missense Mutation (SNP) | VAF 145/424 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SHROOM4 | c.2128T>G p.S710A | Missense Mutation (SNP) | VAF 127/1123 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SLC8A1 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 103/476 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1B | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 108/186 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, varscan2
- SPAG1 | c.1133A>T p.Q378L | Missense Mutation (SNP) | VAF 486/1552 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- STK26 | c.1026A>C p.A342= | Splice Region (SNP) | VAF 55/384 reads (14%) | called by muse, mutect2, varscan2
- SUMF2 | c.818A>C p.K273T (on ENST00000652303; = p.*302Yext*5 on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/556 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TECTA | c.3437A>G p.K1146R | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TERF1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 166/878 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TFAP2E | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 149/434 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TNC | c.5426A>C p.N1809T | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TPTE | c.637dup p.R213Kfs*4 (on ENST00000618007 / NM_199261.4; = p.R195Kfs*4 on NM_199259.4) | Frame Shift Ins (INS) | VAF 24/114 reads (21%) | called by pindel, varscan2
- TRAV12-3 | c.122T>G p.V41G | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TTYH1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- UNK | c.1997A>C p.E666A | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- VPS13B | c.4478T>G p.L1493R | Missense Mutation (SNP) | VAF 67/1017 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- VSIG1 | c.412+1_412+7del p.X138_splice | Splice Site (DEL) | VAF 146/473 reads (31%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 114/587 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF205 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF618 | c.790C>T p.Q264* (on ENST00000374126 / NM_001318042.2; = p.Q252* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 187/435 reads (43%) | called by muse, mutect2, varscan2
- ZNF804B | c.2358A>C p.K786N | Missense Mutation (SNP) | VAF 192/321 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZSCAN20 | c.1172A>T p.K391M | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC068580.4 | c.969C>T p.G323= | Silent (SNP) | VAF 215/338 reads (64%) | catalogued as rs774332555, COSV99362376; called by muse, mutect2, varscan2
- ADCY4 | c.1110C>T p.H370= | Silent (SNP) | VAF 40/468 reads (9%) | called by muse, mutect2
- ADGRB2 | c.1320A>G p.Q440= | Silent (SNP) | VAF 108/494 reads (22%) | called by muse, mutect2, varscan2
- ANKFN1 | c.768G>T p.R256= | Silent (SNP) | VAF 165/283 reads (58%) | catalogued as rs760059035; called by muse, mutect2, varscan2
- ARHGAP6 | c.573C>T p.V191= | Silent (SNP) | VAF 511/683 reads (75%) | called by muse, mutect2, varscan2
- ASCL4 | c.243C>T p.R81= | Silent (SNP) | VAF 307/545 reads (56%) | catalogued as rs1217962466; called by muse, mutect2, varscan2
- BLK | c.601C>T p.L201= | Silent (SNP) | VAF 24/198 reads (12%) | called by muse, mutect2, varscan2
- CEP192 | c.2973G>A p.L991= | Silent (SNP) | VAF 198/217 reads (91%) | called by muse, mutect2, varscan2
- CMIP | c.2175C>T p.D725= (on ENST00000537098 / NM_198390.2; = p.D631= on NM_030629.3) | Silent (SNP) | VAF 222/420 reads (53%) | catalogued as rs745761616; called by muse, mutect2, varscan2
- COL6A3 | c.2304C>T p.R768= | Silent (SNP) | VAF 281/533 reads (53%) | catalogued as rs748301065; called by muse, mutect2, varscan2
- CTNNA2 | c.382A>C p.R128= | Silent (SNP) | VAF 124/578 reads (21%) | called by muse, mutect2, varscan2
- DISP2 | c.3606G>A p.P1202= | Silent (SNP) | VAF 274/667 reads (41%) | catalogued as rs142598891; called by muse, mutect2, varscan2
- EPHA5 | c.831C>T p.S277= | Silent (SNP) | VAF 91/359 reads (25%) | catalogued as rs377555731, COSV99901104; called by muse, mutect2, varscan2
- ESX1 | c.1011G>A p.A337= | Silent (SNP) | VAF 198/1242 reads (16%) | catalogued as rs782565029; called by muse, varscan2
- FAM155B | c.540C>G p.P180= | Silent (SNP) | VAF 662/2073 reads (32%) | called by muse, mutect2, varscan2
- FAM53A | c.414C>A p.R138= | Silent (SNP) | VAF 126/518 reads (24%) | called by muse, mutect2, varscan2
- GJC2 | c.639C>T p.Y213= | Silent (SNP) | VAF 555/582 reads (95%) | called by muse, varscan2
- HRG | c.1542A>G p.Q514= | Silent (SNP) | VAF 41/262 reads (16%) | catalogued as rs757892920; called by muse, mutect2, varscan2
- IL36RN | c.333C>T p.F111= | Silent (SNP) | VAF 234/469 reads (50%) | catalogued as rs199824136, COSV61010530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KARS1 | c.1143A>G p.Q381= | Silent (SNP) | VAF 71/442 reads (16%) | catalogued as rs3211301; called by muse, mutect2, varscan2
- KCTD8 | c.66G>A p.S22= | Silent (SNP) | VAF 333/517 reads (64%) | catalogued as rs1289372697, COSV63598833; called by muse, mutect2, varscan2
- KLHL4 | c.1515G>A p.V505= | Silent (SNP) | VAF 85/516 reads (16%) | called by muse, mutect2, varscan2
- KLKB1 | c.1782C>A p.G594= | Silent (SNP) | VAF 104/342 reads (30%) | called by muse, mutect2, varscan2
- LPA | c.5430A>G p.Q1810= | Silent (SNP) | VAF 62/239 reads (26%) | catalogued as rs770263408, COSV60300733, COSV60312925; called by muse, mutect2, varscan2
- LRBA | c.4113T>C p.A1371= | Silent (SNP) | VAF 71/319 reads (22%) | catalogued as rs866036316; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1104C>T p.C368= | Silent (SNP) | VAF 184/464 reads (40%) | called by muse, mutect2, varscan2
- MATN4 | c.1335C>T p.T445= (on ENST00000372754; = p.T404= on NM_003833.4) | Silent (SNP) | VAF 357/755 reads (47%) | catalogued as rs772372562; called by muse, mutect2, varscan2
- NKAIN4 | c.42C>T p.C14= | Silent (SNP) | VAF 256/569 reads (45%) | catalogued as rs1316115744; called by muse, mutect2, varscan2
- NPHS2 | c.138G>A p.S46= | Silent (SNP) | VAF 34/1232 reads (3%) | catalogued as rs1053139144, COSV62635165; called by muse, mutect2
- POTEF | c.2406C>T p.P802= | Silent (SNP) | VAF 53/756 reads (7%) | catalogued as rs775448822, COSV62541112; called by muse, mutect2
- SCML2 | c.777A>G p.E259= | Silent (SNP) | VAF 102/688 reads (15%) | called by muse, mutect2, varscan2
- SFMBT2 | c.282C>T p.A94= | Silent (SNP) | VAF 239/410 reads (58%) | called by muse, mutect2, varscan2
- SLFN13 | c.2128T>C p.L710= | Silent (SNP) | VAF 89/406 reads (22%) | catalogued as rs1467472792; called by muse, mutect2
- SOGA3 | c.537C>T p.G179= | Silent (SNP) | VAF 516/554 reads (93%) | called by muse, mutect2, varscan2
- SOX11 | c.1254G>A p.T418= | Silent (SNP) | VAF 145/486 reads (30%) | catalogued as COSV58987659; called by muse, varscan2
- TACC2 | c.8640C>T p.H2880= (on ENST00000334433; = p.H958= on NM_006997.4) | Silent (SNP) | VAF 148/262 reads (56%) | catalogued as rs554081729, COSV53277336; called by muse, mutect2, varscan2
- TACO1 | c.813C>T p.P271= | Silent (SNP) | VAF 241/395 reads (61%) | catalogued as rs151139810; called by muse, mutect2, varscan2
- TENM1 | c.2970T>G p.P990= | Silent (SNP) | VAF 136/730 reads (19%) | called by muse, mutect2, varscan2
- TLCD5 | c.222A>G p.Q74= (on ENST00000375095 / NM_001198671.2; = p.Q96= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/271 reads (20%) | called by muse, mutect2, varscan2
- TSPAN2 | c.240C>T p.A80= | Silent (SNP) | VAF 170/317 reads (54%) | called by muse, mutect2, varscan2
- VGLL1 | c.411G>A p.A137= | Silent (SNP) | VAF 302/932 reads (32%) | catalogued as rs772131546; called by muse, mutect2, varscan2
- ZNF185 | c.741G>A p.A247= | Silent (SNP) | VAF 323/544 reads (59%) | catalogued as rs1556870318; called by muse, mutect2, varscan2
- ZNF517 | c.915C>T p.N305= | Silent (SNP) | VAF 1136/1786 reads (64%) | catalogued as rs770165380; called by muse, mutect2, varscan2
- BID | c.362-606A>T | Intron (SNP) | VAF 49/234 reads (21%) | called by muse, mutect2, varscan2
- CMTM1 | c.81+122G>A | Intron (SNP) | VAF 399/761 reads (52%) | catalogued as rs1306010472, COSV104381962; called by muse, mutect2, varscan2
- CORO6 | c.634-522C>A | Intron (SNP) | VAF 266/436 reads (61%) | called by muse, mutect2, varscan2
- FRMPD2 | chr10:48156176 A>C | 3'Flank (SNP) | VAF 29/268 reads (11%) | called by muse, mutect2, varscan2
- KIF3A | c.1228+2050C>T | Intron (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- MAPKAPK5 | chr12:111841603 T>C | 5'Flank (SNP) | VAF 48/185 reads (26%) | called by muse, mutect2, varscan2
- PCLO | c.13300+37A>G | Intron (SNP) | VAF 72/365 reads (20%) | called by muse, mutect2, varscan2
- PDPN | chr1:13583817 G>A | 5'Flank (SNP) | VAF 112/306 reads (37%) | called by muse, mutect2, varscan2
- SPDYE16 | chr7:76541449 G>A | 5'Flank (SNP) | VAF 178/444 reads (40%) | catalogued as rs1431340322; called by muse, mutect2, varscan2
- TP53TG3D | c.*181C>T | 3'UTR (SNP) | VAF 198/420 reads (47%) | catalogued as rs757211265; called by muse, varscan2
